Somatic mutation profile of tumor specimen BA2260D (aliquot aq-BA2260D) from BEATAML1.0 case 2447, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,314 days).
Specimen BA2260D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0acbb7c-e82c-4efe-baef-09c980509650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2920D (Solid Tissue Normal), aliquot aq-BA2920D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ee02ab5-45f5-4741-97ec-2726193e2b27

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, 3'UTR 1, Frame Shift Del 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP131 | c.2281C>T p.R761W (on ENST00000269392 / NM_001319228.2; = p.R758W on NM_014984.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs61746099; called by muse, mutect2, varscan2
- EML1 | c.2312C>T p.S771L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs746865287; called by muse, mutect2, varscan2
- FREM1 | c.4796C>G p.T1599R | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs567441582, COSV66518282; called by muse, mutect2, varscan2
- GLDC | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1286882965; ClinVar: uncertain significance; called by muse, mutect2
- PROC | c.1233C>G p.H411Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52165231; called by muse, mutect2, varscan2
- RANBP17 | c.1645A>G p.I549V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747978034; called by muse, mutect2, varscan2
- SAP25 | c.305C>T p.A102V (on ENST00000538735; = p.A200V on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1265544833; called by muse, mutect2, varscan2
- ADHFE1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, varscan2
- ARHGEF18 | c.2525C>A p.A842E (on ENST00000359920 / NM_001130955.2; = p.A738E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.134); called by muse, mutect2
- FITM1 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.044); called by muse, mutect2
- FRAS1 | c.9470C>A p.A3157E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HYAL3 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2
- IGHA1 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ITGAD | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.74); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTH1R | c.1591C>A p.H531N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAD51AP1 | c.935del p.G312Vfs*11 (on ENST00000228843 / NM_001130862.2; = p.G295Vfs*11 on NM_006479.5) | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- TLR10 | c.1688G>T p.R563M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIM27 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.136); called by muse, mutect2
- DRD4 | c.102C>A p.G34= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99448787; called by muse, mutect2
- GPKOW | c.1179A>G p.V393= | Silent (SNP) | VAF 64/68 reads (94%) | called by muse, mutect2, varscan2
- MXD3 | c.609C>T p.G203= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs778756672; called by muse, mutect2, varscan2
- TFCP2 | c.15G>T p.L5= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- CDIPT | c.-31G>T | 5'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- FAM90A27P | n.593C>A | RNA (SNP) | VAF 4/49 reads (8%) | catalogued as rs1182511246; called by muse, mutect2
- LCN1 | c.*77G>T | 3'UTR (SNP) | VAF 48/102 reads (47%) | catalogued as rs939186811, COSV55018741; called by muse, mutect2, varscan2
